Somatic mutation profile of tumor specimen MP2PRT-PAUVBE-TBP1-A (aliquot MP2PRT-PAUVBE-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAUVBE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,834 days).
Specimen MP2PRT-PAUVBE-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7e2646f-569f-470c-8a8f-d742a444bc77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUVBE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUVBE-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09e6116d-1356-43a1-b9f2-495f9dab3b11

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 17, Silent 5, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A1 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 82/560 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1491002060, COSV62611843; called by muse, mutect2, varscan2
- GALNT2 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 85/326 reads (26%) | catalogued as rs1431963909; called by muse, mutect2, varscan2
- OR4K1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 63/618 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs147602385; called by muse, mutect2
- PCDHA10 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 27/844 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV56479731, COSV56488368; called by muse, mutect2
- SLCO4C1 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as rs145667218; called by muse, mutect2, varscan2
- TUT1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 120/532 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs774549140, COSV53472648; called by muse, mutect2, varscan2
- ANKRD36 | c.2669C>A p.P890Q | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.997); called by muse, mutect2
- BICC1 | c.1963G>T p.A655S | Missense Mutation (SNP) | VAF 105/571 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- C19orf57 | c.1718C>T p.S573L | Missense Mutation (SNP) | VAF 107/339 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CP | c.1600T>G p.C534G | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM110B | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 141/593 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MATK | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2
- MBTPS2 | c.1204C>A p.H402N | Missense Mutation (SNP) | VAF 49/317 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC41A2 | c.129G>T p.L43F | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- SLC9A3 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 159/761 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SPIDR | c.1937G>T p.R646L | Missense Mutation (SNP) | VAF 70/343 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- STAC | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 105/342 reads (31%) | called by muse, mutect2, varscan2
- TNRC6B | c.4832C>A p.S1611* (on ENST00000454349 / NM_001162501.2; = p.S1501* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 145/412 reads (35%) | called by muse, mutect2, varscan2
- TRAJ23 | chr14:22520415 GTGATTTATAACCA>TCCCCCCAG | Missense Mutation (DEL) | VAF 58/393 reads (15%) | called by pindel, varscan2*
- ZNF385B | c.472C>A p.H158N | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR143 | c.723G>A p.V241= | Silent (SNP) | VAF 90/449 reads (20%) | catalogued as rs145665834; called by muse, mutect2, varscan2
- KIF26B | c.1836G>A p.S612= | Silent (SNP) | VAF 385/774 reads (50%) | catalogued as rs1044237441, COSV100832754; called by muse, mutect2, varscan2
- NUAK1 | c.1347G>A p.E449= | Silent (SNP) | VAF 100/484 reads (21%) | catalogued as rs1056232997; called by muse, mutect2
- ROBO1 | c.945G>A p.L315= | Silent (SNP) | VAF 76/238 reads (32%) | called by muse, mutect2, varscan2
- TMTC1 | c.645G>A p.A215= (on ENST00000539277 / NM_001193451.2; = p.A107= on NM_175861.3) | Silent (SNP) | VAF 106/443 reads (24%) | catalogued as rs142412052; called by muse, mutect2, varscan2
